Somatic mutation profile of tumor specimen MBCProject_2783_T1_WES (aliquot MBCProject_2783_T1_WES_1) from CMI case MBCProject_2783, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 45.0 years (16,418 days).
Specimen MBCProject_2783_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25c957dc-d291-45f5-80b2-e975757125d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_2783_SALIVA (Saliva), aliquot MBCProject_2783_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c439f749-d6f2-4f3d-a298-b27517ea21c7

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TNR | c.1115G>A p.R372Q | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs200819640; called by mutect2, varscan2
- ABCA1 | c.2533G>A p.V845I | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.677); called by muse, mutect2
- DHTKD1 | c.1718C>T p.T573I | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DPY19L3 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.092); called by muse, varscan2
- FBXO43 | c.763G>A p.G255S | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- TASOR2 | c.6838G>C p.G2280R | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- DPP8 | c.2559G>A p.K853= (on ENST00000341861 / NM_001320875.2; = p.K737= on NM_017743.6) | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs9920584; called by mutect2, varscan2
- FCRL4 | c.1347G>A p.S449= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as rs748562013; called by muse, mutect2
